Somatic mutation profile of tumor specimen MMRF_2614_1_BM_CD138pos (aliquot MMRF_2614_1_BM_CD138pos_T1_KHS5U_L12839) from MMRF case MMRF_2614, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.3 years (21,292 days).
Specimen MMRF_2614_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e33b3ff1-101a-4de2-8325-26a92b0f7b02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2614_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2614_1_PB_Whole_C3_KHS5U_L12840; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/751739ef-0118-4ad3-99e7-4e7c2e368c26

The open-access MAF lists 99 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 30, Missense Mutation 28, Intron 17, 5'UTR 6, Silent 5, RNA 4, 5'Flank 3, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- EFNA5 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60953980; called by muse, mutect2, varscan2
- EGFR | c.2011C>G p.R671G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV51771628; called by muse, mutect2
- ERGIC2 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs750621603; called by muse, mutect2, varscan2
- FLRT3 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 53/144 reads (37%) | catalogued as rs1486368839, COSV53970142, COSV99428675; called by muse, mutect2, varscan2
- GPANK1 | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs367920721; called by muse, mutect2, varscan2
- IGLV4-3 | c.268T>C p.S90P | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs779458054; called by muse, mutect2, varscan2
- KIR2DL1 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1221479287, COSV99383171, COSV99383774; called by muse, mutect2
- NFIL3 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 287/457 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52683090; called by muse, mutect2, varscan2
- PLCL1 | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as rs542624108; called by muse, mutect2, varscan2
- PUS7 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs143361545; called by muse, mutect2, varscan2
- TPRA1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192330541; called by muse, mutect2, varscan2
- YIPF5 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 19/635 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50823110; called by muse, mutect2
- B4GALT6 | c.798dup p.G267Wfs*12 | Frame Shift Ins (INS) | VAF 86/281 reads (31%) | called by mutect2, pindel, varscan2
- DNAH11 | c.4922C>G p.S1641* | Nonsense Mutation (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- EPHA6 | c.1708T>A p.Y570N | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR25 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- GSG1 | c.713G>A p.R238K (on ENST00000651961 / NM_001080555.4; = p.E243= on NM_031289.5) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- HORMAD2 | c.203T>C p.L68S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HUWE1 | c.2185G>C p.D729H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCNC2 | c.1189G>C p.A397P | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLHL33 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- LYPD1 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2
- MARF1 | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5D13 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2
- OR6T1 | c.588A>C p.K196N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PRSS56 | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SH3PXD2B | c.2510A>G p.E837G | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SLC9B2 | c.1415del p.L472Wfs*12 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | called by pindel, varscan2
- STAG3 | c.939C>T p.Y313= | Splice Region (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- STARD5 | c.517G>C p.V173L | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- SUCLG1 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- TMEM121 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNND2 | c.984G>A p.P328= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- ITIH1 | c.2055C>A p.T685= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs1483714893, COSV56259169; called by muse, mutect2, varscan2
- MPRIP | c.231C>T p.Y77= | Silent (SNP) | VAF 86/260 reads (33%) | catalogued as rs770071686; called by muse, mutect2, varscan2
- NOVA1 | c.555G>A p.L185= | Silent (SNP) | VAF 56/136 reads (41%) | called by muse, varscan2
- PCDHA12 | c.489C>T p.G163= | Silent (SNP) | VAF 25/254 reads (10%) | catalogued as COSV56482924; called by muse, mutect2, varscan2
- ABCC8 | c.1333-96C>G | Intron (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- AC139491.1 | n.1372T>C | RNA (SNP) | VAF 26/846 reads (3%) | called by muse, mutect2
- AK4 | c.*3959A>G | 3'UTR (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- AL049777.1 | n.510+4739A>G | Intron (SNP) | VAF 32/424 reads (8%) | called by muse, mutect2
- ALDH1L1 | c.-14A>C | 5'UTR (SNP) | VAF 61/199 reads (31%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.805A>G | RNA (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*2879T>C | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- C8orf82 | c.*935A>G | 3'UTR (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 5/22 reads (23%) | catalogued as rs73150876; called by mutect2, varscan2
- COPS7A | c.*442A>G | 3'UTR (SNP) | VAF 51/139 reads (37%) | called by muse, mutect2, varscan2
- CYLC2 | c.*185A>G | 3'UTR (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- CYRIA | c.*2930_*2937delinsACAATAAC | 3'UTR (ONP) | VAF 3/35 reads (9%) | called by pindel, varscan2*
- DCTN1 | c.-223A>T | 5'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*5868T>A | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- DPY19L2P4 | n.1618T>A | RNA (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- DSEL | c.*3349C>G | 3'UTR (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- DYNLL1 | c.133-587_133-586del | Intron (DEL) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- ECRG4 | c.285+46T>G | Intron (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- EED | c.727-607C>A | Intron (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- EGR1 | c.-79G>C | 5'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- FAM135A | c.4342+13A>C | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- FAM227B | c.441+354G>T | Intron (SNP) | VAF 61/243 reads (25%) | called by muse, mutect2, varscan2
- GABRP | c.*1394C>T | 3'UTR (SNP) | VAF 5/119 reads (4%) | catalogued as rs1043837455; called by muse, mutect2
- GMEB2 | c.*2425G>A | 3'UTR (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- GP5 | c.*926T>C | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- GPR142 | c.-17T>A | 5'UTR (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100171014; called by muse, mutect2, varscan2
- HACD4 | c.*2645G>A | 3'UTR (SNP) | VAF 33/47 reads (70%) | called by muse, mutect2, varscan2
- IL3RA | c.*209_*210insG | 3'UTR (INS) | VAF 49/124 reads (40%) | called by mutect2, pindel, varscan2
- MAP4 | c.*489T>C | 3'UTR (SNP) | VAF 110/162 reads (68%) | called by muse, mutect2, varscan2
- MBD5 | c.*1158del | 3'UTR (DEL) | VAF 19/77 reads (25%) | catalogued as rs1163189324; called by mutect2, pindel, varscan2
- MOXD1 | c.264+10670A>G | Intron (SNP) | VAF 102/164 reads (62%) | called by muse, mutect2, varscan2
- MRPL37 | c.-65C>T | 5'UTR (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- NEDD4 | c.*2415T>C | 3'UTR (SNP) | VAF 40/63 reads (63%) | called by muse, mutect2, varscan2
- NTRK3 | c.*6088A>C | 3'UTR (SNP) | VAF 49/126 reads (39%) | catalogued as rs1490346797; called by muse, mutect2, varscan2
- NYAP2 | c.*1725G>C | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- OARD1 | c.*1800G>A | 3'UTR (SNP) | VAF 27/113 reads (24%) | catalogued as rs1023205299; called by muse, mutect2, varscan2
- OPRK1 | c.-48-118G>T | Intron (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- PLXNC1 | c.*1911T>C | 3'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- PPARGC1B | c.2971+161G>A | Intron (SNP) | VAF 18/320 reads (6%) | called by muse, mutect2
- PRLR | c.*8981T>G | 3'UTR (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- PTK7 | c.2252-24C>T | Intron (SNP) | VAF 19/90 reads (21%) | catalogued as rs769753879; called by muse, mutect2, varscan2
- RBM5 | c.340-84T>C | Intron (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- RPP30 | chr10:90902308 C>T | 3'Flank (SNP) | VAF 13/21 reads (62%) | catalogued as COSV65471368; called by muse, mutect2, varscan2
- RTL6 | c.*1626C>T | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*3990A>G | 3'UTR (SNP) | VAF 82/150 reads (55%) | called by muse, mutect2, varscan2
- SLC35F5 | c.40+409dup | Intron (INS) | VAF 29/299 reads (10%) | called by mutect2, pindel, varscan2
- STIL | c.*170A>T | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- SYNE4 | c.-10del | 5'UTR (DEL) | VAF 12/71 reads (17%) | called by mutect2, pindel, varscan2
- TIE1 | c.373+19G>A | Intron (SNP) | VAF 59/157 reads (38%) | called by muse, mutect2, varscan2
- TMEM25 | c.-27-176T>C | Intron (SNP) | VAF 115/160 reads (72%) | called by muse, mutect2, varscan2
- TMEM47 | c.*2343T>A | 3'UTR (SNP) | VAF 32/34 reads (94%) | called by muse, mutect2, varscan2
- TMOD3 | c.*428A>T | 3'UTR (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975428 G>C | 5'Flank (SNP) | VAF 50/59 reads (85%) | catalogued as COSV66081661; called by muse, mutect2
- TMSB4X | chrX:12975430 G>A | 5'Flank (SNP) | VAF 52/61 reads (85%) | called by muse, mutect2
- TOMM5 | c.121+129T>C | Intron (SNP) | VAF 86/456 reads (19%) | catalogued as rs1006824572; called by muse, mutect2, varscan2
- TPO | c.*64C>A | 3'UTR (SNP) | VAF 33/513 reads (6%) | called by muse, mutect2
- TRAPPC9 | chr8:140458497 G>T | 5'Flank (SNP) | VAF 41/100 reads (41%) | catalogued as rs1344161108; called by muse, mutect2, varscan2
- TSC1 | c.*4386G>A | 3'UTR (SNP) | VAF 15/94 reads (16%) | catalogued as rs972222981; called by muse, mutect2, varscan2
- TTC9 | c.*2824C>T | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- UBE2W | c.*4472C>T | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2
- ZNF542P | n.675C>T | RNA (SNP) | VAF 26/108 reads (24%) | catalogued as rs1468569865; called by muse, mutect2, varscan2
